Surgical pathology report (de-identified scan), TCGA case TCGA-27-2523, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Milan - Italy, Fondazione IRCCS Instituto Neuroligico C. Besta, specimen TCGA-27-2523-01A (Primary Tumor).

TCGA-27-2523

Ref. Number

Gender

Birth date

Tumor site

Right frontal pre-rolandic

Histological diagnosis

Glioblastoma multiforme

Source: NCI Genomic Data Commons file f6d27ca7-7aa4-41a1-bfc0-56980db3be9b (TCGA-27-2523.13DA443D-2407-4620-8963-F6BD4FB1DAFC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).